Somatic mutation profile of tumor specimen TCGA-VQ-A8P2-01A (aliquot TCGA-VQ-A8P2-01A-11D-A364-08) from TCGA case TCGA-VQ-A8P2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.8 years (25,129 days).
Specimen TCGA-VQ-A8P2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac4b1da4-761a-4238-bbd7-53dab9aa1d5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8P2-10A (Blood Derived Normal), aliquot TCGA-VQ-A8P2-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5209c916-4975-4b04-ae57-457045098b4e

The open-access MAF lists 8,088 somatic variants for this specimen: 5,899 protein-altering or splice-affecting, 1,992 silent, 197 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,868, Silent 1,992, Nonsense Mutation 399, Frame Shift Del 279, Frame Shift Ins 158, Splice Site 126, Intron 79, RNA 49, Splice Region 49, 3'Flank 24, 3'UTR 21, In Frame Del 15.

Variants (750 of 8,088; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1559183717, CM081493, COSV55602700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1557054776, CD107886, CM000642, COSV99497521; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AIFM1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs724160020, CM157338, COSV54855998; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPA | c.244dup p.M82Nfs*8 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs756198538; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BAG3 | c.72dup p.G25Rfs*33 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs727502897; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BMPR1A | c.176del p.L59* | Frame Shift Del (DEL) | VAF 59/158 reads (37%) | catalogued as rs786201038; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1C | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs786205745, COSV59748365, COSV59754731; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKL5 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs267606715, CM085313, CM118357, COSV66111245; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.2424del p.G809Afs*299 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs1114167391, CD123308; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL6A2 | c.1751del p.P584Lfs*12 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs886044398; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV62698994; called by muse, mutect2, varscan2
- DCC | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 64/164 reads (39%) | catalogued as rs1085307773, COSV59101172; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DSP | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs886039343, COSV101131261; ClinVar: pathogenic; called by muse, mutect2
- F7 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs121964931, CM960528; ClinVar: likely pathogenic; called by muse, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2
- FLCN | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as rs879255678, CM051477, COSV53263420; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP2 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as rs1178491246, COSV63493477; ClinVar: pathogenic; called by muse, mutect2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- GNE | c.1009C>T p.R337* (on ENST00000396594 / NM_001128227.3; = p.R306* on NM_005476.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 69/163 reads (42%) | catalogued as rs1057516374, CM156982, COSV64952224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNE | c.922C>T p.R308C (on ENST00000396594 / NM_001128227.3; = p.R277C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs762106720, CM086833, CM139083, COSV64951631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HLCS | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103229, CM960833, COSV100358162; ClinVar: pathogenic; called by muse, mutect2
- HPS5 | c.2593C>T p.R865* (on ENST00000349215 / NM_181507.2; = p.R751* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as rs281865104, CM045582, COSV100752278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HTRA1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs113993968, CM092288, COSV100934744, COSV64563247; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB6 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs140015315, CM142981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KAT6A | c.3353-1G>A p.X1118_splice | Splice Site (SNP) | VAF 66/229 reads (29%) | catalogued as rs1351334408, COSV99704992; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KERA | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as rs386833986, CM053937, COSV99899417; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 46/124 reads (37%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- L1CAM | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852520, CM941030, COSV62831100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MMADHC | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs118204048, CM081188, COSV57573569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYBPC3 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs36211723, CM043542, COSV99920300; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 19/34 reads (56%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PEX1 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs1057517480, COSV99952080; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIGL | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795400, COSV99848587; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PNPLA6 | c.787G>A p.V263I (on ENST00000414982 / NM_001166111.2; = p.V215I on NM_006702.5) | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs587777184, CM1213206, COSV99653614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57673247, COSV57678855; called by muse, mutect2, varscan2
- PRF1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs28933376, CM030491, COSV64615387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PUS3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs576405108, COSV99916902, COSV99916975; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 60/135 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV69041520, COSV69042084; called by muse, mutect2, varscan2
- RHOBTB2 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1563292586, COSV99310930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 79/212 reads (37%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- SCN1A | c.1118del p.L373Cfs*6 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | catalogued as rs794726695, CD1311682; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN5A | c.4912C>T p.R1638* (on ENST00000333535 / NM_198056.3; = p.R1637* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as rs761505217, CM067020, COSV61123596, COSV61144164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 36/72 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- USH2A | c.13576C>T p.R4526* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | catalogued as rs1003869920, CM115977, COSV56326318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VARS1 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs769369302, CM1512604, COSV100791806; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WFS1 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs387906930, CM015844, CM108446, COSV56990418; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WNT7A | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs104893832, CM063229, COSV99541278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZFYVE26 | c.4132C>T p.R1378* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs774809466, COSV61327754; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs1309067397, COSV59389278; called by muse, mutect2, varscan2
- A2ML1 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs375392265; called by muse, mutect2, varscan2
- A2ML1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100228884; called by muse, mutect2, varscan2
- AADACL4 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66107160; called by muse, mutect2
- AADAT | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61786973; called by muse, mutect2, varscan2
- AAK1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101275954; called by muse, mutect2, varscan2
- AARS1 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); catalogued as COSV99933462; called by muse, mutect2, varscan2
- AASS | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100741770, COSV100741883; called by muse, varscan2
- ABCA1 | c.5729A>T p.D1910V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV101036876; called by muse, mutect2, varscan2
- ABCA1 | c.4627C>T p.Q1543* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV101036877; called by muse, mutect2, varscan2
- ABCA10 | c.2160A>G p.I720M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV99288569; called by muse, mutect2, varscan2
- ABCA13 | c.8350G>T p.G2784* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs1451626921, COSV101446934; called by muse, varscan2
- ABCA13 | c.8636G>A p.S2879N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs1036518252, COSV101446935; called by muse, mutect2, varscan2
- ABCA2 | c.4505C>T p.A1502V (on ENST00000614293; = p.A1472V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1234582723, COSV55803758; called by muse, varscan2
- ABCA2 | c.4130C>T p.A1377V (on ENST00000614293; = p.A1347V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs747657286, COSV55798161; called by muse, varscan2
- ABCA3 | c.5006C>T p.A1669V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV100068409; called by muse, varscan2
- ABCA4 | c.5765C>A p.A1922D | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1178700065, COSV100933117; called by muse, mutect2, varscan2
- ABCA4 | c.4438A>G p.T1480A | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs1205633762, COSV64676806; called by muse, mutect2, varscan2
- ABCA5 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs375901989; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA6 | c.743dup p.S249Vfs*2 | Frame Shift Ins (INS) | VAF 31/88 reads (35%) | catalogued as rs1420043730; called by mutect2, pindel, varscan2
- ABCA7 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.497); catalogued as rs1385843892, COSV99565683; called by muse, mutect2, varscan2
- ABCA7 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs373849833, COSV99565685; called by muse, mutect2, varscan2
- ABCB1 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99712905; called by muse, mutect2, varscan2
- ABCB8 | c.1981C>T p.R661C (on ENST00000297504 / NM_001282291.2; = p.R644C on NM_007188.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387592190, COSV99874324; called by muse, mutect2, varscan2
- ABCB9 | c.1541G>A p.R514H (on ENST00000280560 / NM_019625.4; = p.R471H on NM_019624.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs756697048, COSV99757690; called by muse, varscan2
- ABCC12 | c.1998G>T p.E666D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100252627; called by muse, mutect2, varscan2
- ABCC2 | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100966494; called by muse, mutect2, varscan2
- ABCC2 | c.3011C>T p.T1004I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs775253982, COSV100966495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC3 | c.4220T>C p.F1407S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99559090; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.876); catalogued as COSV52741265, COSV99228673; called by muse, mutect2, varscan2
- ABCC8 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758618229, COSV100217204; called by muse, mutect2, varscan2
- ABCE1 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1282696739, COSV56846407; called by muse, mutect2, varscan2
- ABCF1 | c.2330C>T p.S777F (on ENST00000326195 / NM_001025091.2; = p.S739F on NM_001090.3) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58230611; called by muse, mutect2, varscan2
- ABCF2 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 40/100 reads (40%) | catalogued as rs1466508250, COSV99734362; called by muse, mutect2, varscan2
- ABCF3 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs556532781, COSV53047409; called by muse, mutect2, varscan2
- ABCG2 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs751279458, COSV99419153; called by muse, mutect2, varscan2
- ABCG8 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV99699766; called by muse, mutect2
- ABHD10 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99845027; called by muse, mutect2
- ABHD12 | c.896G>A p.W299* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100194392; called by muse, mutect2, varscan2
- ABHD12B | c.596_597del p.Y199* (on ENST00000337334 / NM_001206673.2; = p.Y122* on NM_181533.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | catalogued as rs772027493; called by mutect2, pindel, varscan2
- ABHD12B | c.968A>G p.Y323C (on ENST00000337334 / NM_001206673.2; = p.Y246C on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99368587; called by muse, mutect2, varscan2
- ABHD14A | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs147333161; called by muse, mutect2, varscan2
- ABHD2 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100756265; called by muse, mutect2, varscan2
- ABHD4 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144917490; called by mutect2, varscan2
- ABHD8 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99917239; called by muse, mutect2, varscan2
- ABI1 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs1278496027, COSV100697859; called by muse, mutect2, varscan2
- ABL2 | c.2920C>T p.R974* (on ENST00000502732 / NM_007314.4; = p.R959* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV100772691; called by muse, mutect2, varscan2
- ABLIM3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs1223706975, COSV100448332; called by muse, mutect2, varscan2
- AC005833.1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious, low confidence (0); catalogued as rs1374451872, COSV99362773; called by muse, mutect2, varscan2
- AC006059.2 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs756581513, COSV59606937; called by muse, mutect2, varscan2
- AC008676.3 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV56637295; called by muse, mutect2, varscan2
- AC013489.1 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as COSV99183860; called by muse, mutect2, varscan2
- AC090517.4 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99974426; called by muse, mutect2, varscan2
- AC097637.1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as rs761464663, COSV59727445; called by muse, mutect2, varscan2
- AC098582.1 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018883, COSV52022658; called by muse, mutect2, varscan2
- AC126283.2 | c.1176A>G p.I392M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1471507953, COSV101144402; called by muse, mutect2, varscan2
- ACAA2 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99551819; called by muse, varscan2
- ACAA2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760617913, COSV53270009; called by muse, varscan2
- ACACB | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100622815; called by muse, mutect2, varscan2
- ACAD10 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100564120, COSV100564699; called by muse, varscan2
- ACAD11 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99391961; called by muse, mutect2, varscan2
- ACADM | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM088188, COSV100273472; called by muse, mutect2, varscan2
- ACADVL | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as rs769885223, COSV99138487; called by muse, mutect2, varscan2
- ACCS | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs751260407, COSV55460246; called by muse, mutect2, varscan2
- ACE2 | c.1012A>G p.N338D | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99382767; called by muse, mutect2, varscan2
- ACER1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs767045996, COSV100034013; called by muse, mutect2, varscan2
- ACIN1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV52972567; called by muse, mutect2, varscan2
- ACKR2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99825499; called by muse, mutect2, varscan2
- ACKR3 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56021976, COSV99799531; called by muse, mutect2
- ACOT1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs375253960, COSV58570851; called by mutect2, varscan2
- ACOT6 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV101141929; called by muse, mutect2, varscan2
- ACOX2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs138799827; called by muse, mutect2, varscan2
- ACP3 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100313333; called by muse, mutect2, varscan2
- ACSBG1 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99357353; called by muse, mutect2, varscan2
- ACSBG2 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99397388; called by muse, mutect2, varscan2
- ACSBG2 | c.861A>G p.I287M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.129); catalogued as COSV99397390; called by muse, mutect2, varscan2
- ACSL5 | c.467C>T p.S156F (on ENST00000354273; = p.S212F on NM_016234.3) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100634573, COSV61129469; called by muse, mutect2
- ACSM5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776309636, COSV59375732; called by muse, mutect2, varscan2
- ACSM5 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV100088861; called by muse, mutect2, varscan2
- ACTC1 | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV99291574; called by muse, mutect2, varscan2
- ACTL7B | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1443222369, COSV101012517; called by muse, mutect2, varscan2
- ACTL8 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs746694408, COSV100958615; called by muse, mutect2, varscan2
- ACTN3 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.737); catalogued as COSV72207630; called by muse, mutect2, varscan2
- ACTN3 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs199897168, COSV72207634; called by muse, mutect2, varscan2
- ACTN3 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs758580966, COSV59750770, COSV59750906; called by muse, mutect2, varscan2
- ACTR3B | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99753971; called by muse, mutect2, varscan2
- ACVR2A | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs770920471, COSV54021831; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 64/77 reads (83%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs767764795, COSV101187825; called by muse, mutect2
- ADAD1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as rs760493563, COSV99634982; called by muse, mutect2, varscan2
- ADAM12 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100903317; called by muse, mutect2, varscan2
- ADAM12 | c.1417T>G p.C473G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100900409; called by muse, mutect2, varscan2
- ADAM19 | c.1649C>T p.T550I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as COSV99977042; called by muse, mutect2, varscan2
- ADAM22 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV99716717; called by muse, mutect2, varscan2
- ADAM22 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV99716718; called by muse, mutect2, varscan2
- ADAM30 | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778815352, COSV101023848; called by muse, mutect2, varscan2
- ADAM7 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV99443804; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS10 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV99546862; called by muse, mutect2, varscan2
- ADAMTS10 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs573956702, COSV54354389; called by muse, mutect2, varscan2
- ADAMTS12 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710840; called by muse, mutect2, varscan2
- ADAMTS14 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs770167458, COSV64600378; called by muse, mutect2, varscan2
- ADAMTS16 | c.1469G>A p.C490Y | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56998907; called by muse, mutect2, varscan2
- ADAMTS17 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs762883961, COSV51488431, COSV99170605; called by muse, mutect2, varscan2
- ADAMTS19 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs892700569, COSV99177533; called by muse, mutect2, varscan2
- ADAMTS19 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 43/115 reads (37%) | catalogued as rs1561644815, COSV50731472; called by muse, mutect2, varscan2
- ADAMTS2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146441575; called by mutect2, varscan2
- ADAMTS2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371384169; called by muse, mutect2, varscan2
- ADAMTS2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs535377243, COSV99201761; called by mutect2, varscan2
- ADAMTS2 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99201798; called by muse, mutect2, varscan2
- ADAMTS3 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV99710974; called by muse, mutect2, varscan2
- ADAMTS3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99710976; called by muse, mutect2, varscan2
- ADAMTS3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs1326633039, COSV54393820; called by muse, mutect2, varscan2
- ADAMTS4 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as rs1263782206, COSV63489692, COSV63491166; called by muse, mutect2, varscan2
- ADAMTS4 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs778329496, COSV63490491; called by mutect2, varscan2
- ADAMTS5 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as rs1163793755, COSV99537535; called by muse, mutect2, varscan2
- ADAMTS7 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751121773, COSV101183094; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4837T>C p.C1613R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99718607; called by muse, mutect2, varscan2
- ADCK1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200211943, COSV53079681; called by muse, mutect2, varscan2
- ADCY1 | c.2311G>A p.G771R | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as rs200275390, COSV99811894; called by muse, mutect2, varscan2
- ADCY2 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243719617, COSV57886381; called by muse, mutect2, varscan2
- ADCY3 | c.1946T>C p.V649A | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV99568186; called by muse, mutect2, varscan2
- ADCY3 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53171685, COSV99568187; called by muse, mutect2, varscan2
- ADCY5 | c.3559G>A p.G1187R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455176936, COSV100567134, COSV100567373; called by muse, varscan2
- ADCY5 | c.2092T>G p.F698V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV100567643; called by muse, mutect2, varscan2
- ADCY6 | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); catalogued as COSV100326596; called by muse, mutect2, varscan2
- ADD2 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.953); catalogued as rs377424595; called by muse, mutect2, varscan2
- ADD3 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as rs1422540227, COSV99523367; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs750027952, COSV100177894; called by muse, mutect2, varscan2
- ADGRB1 | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs577805420, COSV60100189; called by muse, mutect2, varscan2
- ADGRB2 | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1359227086, COSV99926162; called by muse, mutect2, varscan2
- ADGRB3 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.114); catalogued as COSV101000580; called by muse, mutect2
- ADGRB3 | c.3218C>T p.T1073M | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs376079687; called by muse, mutect2, varscan2
- ADGRB3 | c.3371G>A p.R1124H | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs149298585; called by muse, mutect2, varscan2
- ADGRB3 | c.3763G>T p.G1255C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.436); catalogued as COSV99484915; called by muse, mutect2, varscan2
- ADGRD1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370807516; called by muse, mutect2, varscan2
- ADGRD1 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs764133268, COSV55445813; called by muse, varscan2
- ADGRE2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100215978; called by muse, mutect2, varscan2
- ADGRF2 | c.380C>T p.T127I (on ENST00000296862 / NM_001368115.2; = p.T59I on NM_153839.7) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as rs753237829, COSV99731133; called by muse, mutect2, varscan2
- ADGRL1 | c.3965C>T p.A1322V (on ENST00000340736 / NM_001008701.3; = p.A1317V on NM_014921.5) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs773893693, COSV100529451; called by muse, varscan2
- ADGRL2 | c.853A>C p.M285L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99588827; called by muse, mutect2, varscan2
- ADGRL2 | c.2501G>A p.R834K (on ENST00000370717 / NM_001366005.1; = p.R821K on NM_012302.4) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.313); catalogued as COSV99588835; called by muse, mutect2, varscan2
- ADGRL4 | c.1867C>T p.L623F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100875921; called by muse, mutect2, varscan2
- ADGRV1 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101315840; called by muse, mutect2, varscan2
- ADGRV1 | c.9085A>G p.I3029V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV101315841; called by muse, mutect2
- ADGRV1 | c.15358G>A p.A5120T | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101315842; called by muse, mutect2, varscan2
- ADH7 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs141729668, COSV52924044; called by muse, mutect2, varscan2
- ADIPOQ | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1251114575, COSV100292151; called by muse, mutect2, varscan2
- ADIPOR2 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100840088; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP2 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100080799; called by muse, mutect2
- ADORA2B | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs780529349, COSV58482827, COSV58483558; called by muse, mutect2, varscan2
- ADORA3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs746154553, COSV53987170; called by muse, varscan2
- ADPRS | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs759989977, COSV99255502; called by muse, mutect2, varscan2
- ADRA2A | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755773499, COSV54528248; called by muse, mutect2, varscan2
- AEBP1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs750288301, COSV99788747; called by muse, mutect2, varscan2
- AFAP1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV61792826; called by muse, mutect2, varscan2
- AFAP1 | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV61794023; called by muse, mutect2, varscan2
- AFAP1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460080895, COSV100631455; called by muse, mutect2, varscan2
- AFAP1L2 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs1354871997, COSV58419891; called by muse, mutect2, varscan2
- AFDN | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs769754520, COSV60043738, COSV60062275; called by muse, mutect2, varscan2
- AFF1 | c.3201del p.D1068Tfs*2 | Frame Shift Del (DEL) | VAF 40/118 reads (34%) | catalogued as rs1212211089; called by mutect2, pindel, varscan2
- AFF1 | c.3589C>T p.R1197* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV57123051; called by muse, mutect2
- AFF2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 83/112 reads (74%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV100649981, COSV60671680; called by muse, mutect2, varscan2
- AFG3L2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV99301837; called by muse, mutect2, varscan2
- AFG3L2 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs369885409; called by muse, mutect2, varscan2
- AGAP1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV100364982; called by muse, mutect2, varscan2
- AGAP1 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.416); catalogued as rs753271398, COSV100364225, COSV58318458; called by muse, mutect2, varscan2
- AGAP2 | c.2770C>T p.R924C (on ENST00000547588 / NM_001122772.2; = p.R568C on NM_014770.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99223049; called by muse, mutect2, varscan2
- AGAP2 | c.1546C>T p.Q516* (on ENST00000547588 / NM_001122772.2; = p.Q180* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs1033449215, COSV99223051; called by muse, mutect2, varscan2
- AGAP3 | c.781G>A p.G261R (on ENST00000622464; = p.G297R on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs1361764019, COSV100103804; called by muse, mutect2, varscan2
- AGAP6 | c.1805G>A p.C602Y (on ENST00000374056 / NM_001365867.1; = p.C625Y on NM_001077665.2) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.943); catalogued as rs1554865552, COSV100929082; called by muse, mutect2, varscan2
- AGBL1 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101222919; called by muse, mutect2
- AGGF1 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs776049702, COSV57230883; called by muse, mutect2, varscan2
- AGK | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.262); catalogued as COSV100814612; called by muse, mutect2
- AGL | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649129; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 38/208 reads (18%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AGO2 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV55046413; called by muse, mutect2
- AGO2 | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV99595662; called by muse, mutect2, varscan2
- AGPAT2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs755548321, COSV100451964; called by muse, mutect2, varscan2
- AGXT2 | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99183746; called by muse, mutect2, varscan2
- AHCTF1 | c.4516C>T p.P1506S (on ENST00000366508; = p.P1480S on NM_015446.5) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.053); catalogued as rs1558214449, COSV100403590; called by muse, mutect2, varscan2
- AHCY | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs867752341, COSV54152605; called by muse, mutect2
- AHDC1 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs138355578; ClinVar: benign; called by muse, mutect2, varscan2
- AHDC1 | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV99899255; called by muse, varscan2
- AHDC1 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367582615, CM1412546, COSV55940143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.6398C>T p.A2133V | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.97); catalogued as rs554709190, COSV100317361; called by muse, mutect2, varscan2
- AHNAK2 | c.6170C>T p.P2057L | Missense Mutation (SNP) | VAF 102/110 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs561933027; called by muse, mutect2, varscan2
- AHR | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99619648; called by muse, mutect2, varscan2
- AHSG | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as COSV99890000; called by muse, mutect2, varscan2
- AHSG | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV56606886; called by muse, mutect2, varscan2
- AIFM3 | c.1239G>T p.K413N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV99301694; called by muse, mutect2, varscan2
- AIMP2 | c.708G>A p.W236* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs779256399, COSV99551854; called by muse, mutect2, varscan2
- AK5 | c.1307C>T p.P436L (on ENST00000354567 / NM_174858.3; = p.P410L on NM_012093.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV100642648; called by muse, mutect2
- AK9 | c.5677T>G p.F1893V | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV69850225; called by muse, mutect2, varscan2
- AKAP13 | c.2855G>T p.R952I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV100773693; called by muse, mutect2, varscan2
- AKAP4 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100654247; called by muse, mutect2, varscan2
- AKAP6 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99800508; called by muse, mutect2, varscan2
- AKAP6 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868161302, COSV55209617; called by muse, mutect2, varscan2
- AKAP8L | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs376232500; called by muse, mutect2, varscan2
- AKNAD1 | c.1537-1G>A p.X513_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100645503; called by muse, mutect2, varscan2
- AKNAD1 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 37/89 reads (42%) | catalogued as COSV100645504; called by muse, mutect2, varscan2
- AKR1A1 | c.912+1G>T p.X304_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100698715; called by muse, mutect2, varscan2
- AKR1B15 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101423369; called by muse, mutect2, varscan2
- AKR1D1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV99653028; called by muse, mutect2, varscan2
- AKR7A2 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1558138539, COSV99352024; called by muse, mutect2, varscan2
- AKR7A3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs756610725, COSV64389201; called by muse, mutect2, varscan2
- AKT1S1 | c.627G>A p.P209= (on ENST00000344175 / NM_001098633.4; = p.P229= on NM_032375.5) | Splice Region (SNP) | VAF 70/177 reads (40%) | catalogued as rs199687596; called by muse, mutect2, varscan2
- AKT2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs763951605, COSV60908240; called by muse, mutect2, varscan2
- AKT2 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100251598; called by muse, mutect2, varscan2
- AKT3 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV55612829, COSV99795260; called by muse, mutect2, varscan2
- AKTIP | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs757341232, COSV100043601, COSV50892304; called by muse, mutect2, varscan2
- AL121899.2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs143797112; called by muse, mutect2
- AL121899.2 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101198443; called by muse, mutect2, varscan2
- AL441992.2 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV56915751; called by muse, mutect2
- AL592490.1 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101308174; called by muse, mutect2, varscan2
- AL592490.1 | c.2336T>C p.V779A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV69426809; called by muse, mutect2, varscan2
- AL592490.1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.035); catalogued as COSV69425427; called by muse, varscan2
- AL592490.1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV101308178, COSV69424337; called by muse, varscan2
- AL645922.1 | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV64888192; called by muse, mutect2, varscan2
- ALAS2 | c.1013G>A p.C338Y | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100238243; called by muse, varscan2
- ALDH16A1 | c.2168C>T p.T723I | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99512850; called by muse, mutect2, varscan2
- ALDH1L2 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99310991; called by muse, mutect2, varscan2
- ALDH2 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99922925; called by muse, varscan2
- ALDH3A1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV56735029; called by muse, mutect2, varscan2
- ALDH7A1 | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs989375168, COSV100778265; ClinVar: uncertain significance; called by muse, mutect2
- ALDH9A1 | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100699299; called by muse, mutect2, varscan2
- ALDOB | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as CM082485, COSV100878858, COSV100878961; called by muse, mutect2, varscan2
- ALDOB | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV100878859; called by muse, mutect2, varscan2
- ALG11 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV101584277; called by muse, mutect2, varscan2
- ALG11 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101584278, COSV101584297; called by muse, mutect2, varscan2
- ALG14 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV100930853; called by muse, mutect2, varscan2
- ALKBH1 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99380567; called by muse, mutect2, varscan2
- ALKBH4 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs761966095, COSV52962785; called by muse, mutect2, varscan2
- ALMS1 | c.6248T>C p.V2083A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV100042293; called by muse, mutect2, varscan2
- ALMS1 | c.9635C>T p.T3212I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100042296, COSV52501823; called by muse, mutect2, varscan2
- ALOX12 | c.1670C>A p.A557D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1416623522, COSV52351502, COSV99278082; called by muse, mutect2, varscan2
- ALOX12B | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100047036; called by muse, mutect2, varscan2
- ALOX15B | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769849124, COSV101205614; called by muse, mutect2, varscan2
- ALPI | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs554429184, COSV55013413; called by muse, mutect2, varscan2
- ALPK1 | c.3035G>A p.S1012N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1560689631, COSV51582668; called by muse, varscan2
- ALPK2 | c.5875G>A p.A1959T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs375621243; called by muse, mutect2, varscan2
- ALS2CL | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200646143, COSV100014990, COSV59672218; called by muse, mutect2, varscan2
- AMBRA1 | c.3260C>T p.A1087V (on ENST00000458649 / NM_001367468.1; = p.A997V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1412921665, COSV100093830; called by muse, mutect2, varscan2
- AMBRA1 | c.1114A>G p.S372G (on ENST00000458649 / NM_001367468.1; = p.S282G on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as rs1450981692, COSV100093838; called by muse, mutect2, varscan2
- AMER1 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs772338892, COSV100365991; called by muse, mutect2, varscan2
- AMER2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV100766240; called by muse, mutect2
- AMIGO3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs1303356074, COSV57540037; called by muse, mutect2, varscan2
- AMMECR1L | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99761361; called by muse, mutect2, varscan2
- AMOTL2 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99850637; called by muse, mutect2, varscan2
- AMOTL2 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780963891, COSV99998154; called by muse, mutect2, varscan2
- AMPD1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147035391; called by muse, varscan2
- AMPD3 | c.1402C>T p.R468C (on ENST00000396553 / NM_001025389.2; = p.R477C on NM_000480.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs147091692; called by muse, mutect2, varscan2
- AMZ2 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100703151; called by muse, mutect2, varscan2
- ANAPC1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1288534326, COSV100594686, COSV61974363; called by muse, mutect2, varscan2
- ANAPC13 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100132730; called by muse, mutect2, varscan2
- ANGPT1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV52447577; called by muse, mutect2, varscan2
- ANGPT2 | c.1271G>T p.S424I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100290886; called by muse, mutect2, varscan2
- ANGPTL7 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as rs1223845024, COSV100816124; called by muse, mutect2, varscan2
- ANGPTL7 | c.1025A>G p.E342G | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as COSV100816126; called by muse, mutect2, varscan2
- ANK1 | c.5341G>T p.G1781C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as rs757408601, COSV99225069; called by muse, mutect2, varscan2
- ANK1 | c.4894A>G p.N1632D | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.164); catalogued as COSV99225072; called by muse, mutect2, varscan2
- ANK1 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99225076; called by muse, mutect2, varscan2
- ANK1 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749623248, COSV55889703, COSV99225589; called by muse, varscan2
- ANK1 | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478581881, COSV55872922; called by muse, varscan2
- ANK1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs563833117, COSV55884212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as rs1466658148; called by mutect2, varscan2
- ANK3 | c.11765A>T p.N3922I | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV99779716; called by muse, mutect2, varscan2
- ANK3 | c.6332C>T p.S2111F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV99779717; called by muse, mutect2, varscan2
- ANK3 | c.4396C>T p.R1466C (on ENST00000280772 / NM_001320874.2; = p.R591C on NM_001149.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs763194402, COSV99779719; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANK3 | c.2726C>T p.A909V (on ENST00000280772 / NM_001320874.2; = p.A43V on NM_001149.3) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as rs768866559, COSV99779725; called by muse, mutect2, varscan2
- ANKAR | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV99854190; called by muse, mutect2, varscan2
- ANKAR | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV99854172, COSV99854192; called by muse, mutect2, varscan2
- ANKDD1A | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201858103, COSV100731166; called by muse, mutect2, varscan2
- ANKEF1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV101001019, COSV65692358; called by muse, mutect2, varscan2
- ANKFY1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.433); catalogued as rs376997211, COSV100492626; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6596C>T p.S2199F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99783174; called by muse, mutect2, varscan2
- ANKLE2 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100514089; called by muse, mutect2, varscan2
- ANKMY1 | c.2354G>A p.G785D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99802071; called by muse, mutect2, varscan2
- ANKRD11 | c.4697C>A p.A1566D | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99969171; called by muse, mutect2, varscan2
- ANKRD11 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750217123, COSV99969173; called by mutect2, varscan2
- ANKRD12 | c.4527G>A p.M1509I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs143090707; called by muse, mutect2, varscan2
- ANKRD12 | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100040559, COSV100041208; called by muse, mutect2, varscan2
- ANKRD13A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs766253422, COSV55677069; called by muse, mutect2, varscan2
- ANKRD17 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100429141; called by muse, mutect2, varscan2
- ANKRD20A4P | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100628522; called by mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD23 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100450411; called by muse, mutect2, varscan2
- ANKRD27 | c.1163G>T p.S388I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100042766; called by muse, mutect2, varscan2
- ANKRD33 | c.218C>T p.A73V (on ENST00000340970 / NM_001304459.2; = p.A208V on NM_182608.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1300387418, COSV100001274; called by muse, mutect2, varscan2
- ANKRD42 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1194138541, COSV52615611, COSV99473771; called by muse, mutect2, varscan2
- ANKRD45 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100322477, COSV60961393; called by muse, mutect2, varscan2
- ANKRD50 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV101538946; called by muse, mutect2, varscan2
- ANKRD50 | c.1853C>A p.A618D | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101538947; called by muse, mutect2, varscan2
- ANKRD55 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100591269; called by muse, mutect2, varscan2
- ANO1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs778999525, COSV60284006; called by muse, mutect2, varscan2
- ANO2 | c.364G>A p.V122I (on ENST00000356134 / NM_001278597.3; = p.V126I on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1299653264, COSV59006843; called by muse, mutect2
- ANO4 | c.581G>A p.R194H (on ENST00000392977 / NM_001286615.2; = p.R159H on NM_178826.4) | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.693); catalogued as rs752635853, COSV100152067; called by muse, mutect2, varscan2
- ANO4 | c.1405C>T p.R469* (on ENST00000392977 / NM_001286615.2; = p.R434* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as rs775993661, COSV100151219; called by muse, mutect2, varscan2
- ANO4 | c.1834G>A p.A612T (on ENST00000392977 / NM_001286615.2; = p.A577T on NM_178826.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1337882537, COSV100152792; called by muse, mutect2, varscan2
- ANO4 | c.2369C>T p.A790V (on ENST00000392977 / NM_001286615.2; = p.A755V on NM_178826.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763712389, COSV100151981; called by muse, mutect2, varscan2
- ANP32E | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 39/79 reads (49%) | catalogued as COSV100029658; called by muse, mutect2, varscan2
- ANPEP | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs746685166, COSV100263011; called by muse, mutect2, varscan2
- ANPEP | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as rs375160446; called by muse, mutect2, varscan2
- ANXA1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57411031; called by muse, mutect2, varscan2
- ANXA1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1369672677, COSV99973915; called by muse, mutect2, varscan2
- ANXA1 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV99973918; called by muse, mutect2, varscan2
- ANXA11 | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV99627087; called by muse, mutect2, varscan2
- ANXA13 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1173790349, COSV99146102; called by muse, mutect2, varscan2
- ANXA2 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV100221988; called by muse, mutect2, varscan2
- ANXA5 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99634344; called by muse, mutect2, varscan2
- AOC1 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs756815729, COSV62871023; called by muse, mutect2, varscan2
- AOX1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs146370823; called by muse, mutect2, varscan2
- AP002748.5 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs747459381, COSV59147332, COSV59149630; called by muse, mutect2, varscan2
- AP1B1 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as rs144652436; called by muse, mutect2, varscan2
- AP1G1 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100250387; called by muse, mutect2, varscan2
- AP1G1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as rs774004811, COSV100250388; called by muse, mutect2, varscan2
- AP1G2 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs1260537467, COSV100436680; called by muse, mutect2, varscan2
- AP2A1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100756260; called by muse, mutect2, varscan2
- AP2M1 | c.1267C>A p.R423S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53047300, COSV99490552; called by muse, mutect2, varscan2
- AP4B1 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870760; called by muse, mutect2, varscan2
- AP4E1 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99956591; called by muse, mutect2, varscan2
- AP4E1 | c.2652A>C p.E884D | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); catalogued as COSV99956593; called by muse, mutect2, varscan2
- AP4M1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV100384870; called by muse, mutect2, varscan2
- APBA3 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs1371876700, COSV99516023; called by muse, mutect2, varscan2
- APBB1IP | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100770892; called by muse, mutect2, varscan2
- APC | c.4687C>A p.L1563I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99967603; called by muse, mutect2, varscan2
- APC2 | c.5362C>A p.L1788I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as rs1367752510, COSV99279392; called by muse, mutect2
- APCDD1L | c.235T>G p.F79V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1168438273, COSV100953986; called by muse, mutect2, varscan2
- APEX1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1471676715, COSV99164475; called by muse, mutect2, varscan2
- API5 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs543630471, COSV101124531; called by mutect2, varscan2
- APMAP | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99468520; called by muse, mutect2, varscan2
- APOB | c.8753A>G p.H2918R | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV99265424; called by muse, mutect2, varscan2
- APOB | c.8111C>T p.A2704V | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs201874707, COSV51930390, COSV51960377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.5455C>A p.L1819M | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99265426; called by muse, mutect2, varscan2
- APOBEC1 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99981056, COSV99981091; called by muse, mutect2, varscan2
- APOBEC3C | c.447C>A p.D149E | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV53328467; called by muse, mutect2, varscan2
- APOBEC3F | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV100415183, COSV57910940; called by muse, mutect2, varscan2
- APOBEC4 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs778262711, COSV58016975; called by muse, mutect2, varscan2
- APOL3 | c.1007G>A p.G336E (on ENST00000349314 / NM_145640.2; = p.G265E on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); catalogued as COSV100652062; called by muse, mutect2, varscan2
- APOL4 | c.218G>T p.R73M (on ENST00000352371 / NM_145660.2; = p.R70M on NM_030643.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs1156370552, COSV100113190; called by muse, mutect2, varscan2
- APP | c.1780A>G p.M594V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as rs1330429266, COSV100695698; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP2 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs780992666, COSV99550811; called by muse, mutect2, varscan2
- AQR | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.577); catalogued as COSV99333876; called by muse, mutect2
- ARAP2 | c.3884A>G p.E1295G | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV100394577; called by muse, mutect2, varscan2
- ARAP2 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs200994795; called by muse, mutect2, varscan2
- ARAP3 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs146818768; called by mutect2, varscan2
- ARFGAP1 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as rs753369595, COSV100796674; called by muse, mutect2, varscan2
- ARFGEF1 | c.5393C>A p.A1798D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.439); catalogued as COSV99138471; called by muse, mutect2, varscan2
- ARFGEF1 | c.5320C>T p.R1774* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | catalogued as COSV51588024; called by muse, mutect2
- ARFGEF1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs200392828, COSV51620792; called by muse, mutect2, varscan2
- ARFGEF2 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100904236; called by muse, mutect2, varscan2
- ARFGEF2 | c.5138T>C p.L1713S | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100904239; called by muse, mutect2
- ARFGEF3 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs760709862, COSV99293330; called by muse, mutect2, varscan2
- ARFIP2 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV99601507; called by muse, mutect2, varscan2
- ARHGAP1 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100305458; called by muse, mutect2, varscan2
- ARHGAP11A | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs1487117985, COSV64381180; called by muse, mutect2, varscan2
- ARHGAP12 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV100260573; called by muse, mutect2, varscan2
- ARHGAP18 | c.488del p.N163Tfs*55 | Frame Shift Del (DEL) | VAF 56/140 reads (40%) | catalogued as rs749346165; called by mutect2, varscan2
- ARHGAP20 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs749876784, COSV99503899; called by muse, mutect2, varscan2
- ARHGAP25 | c.373G>A p.G125R (on ENST00000409202 / NM_001007231.3; = p.G118R on NM_014882.3) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54903844; called by muse, mutect2, varscan2
- ARHGAP25 | c.1207G>A p.D403N (on ENST00000409202 / NM_001007231.3; = p.D395N on NM_014882.3) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1315038079, COSV54901830, COSV99771487; called by muse, mutect2, varscan2
- ARHGAP27 | c.1543C>A p.L515I (on ENST00000428638 / NM_001282290.1; = p.L174I on NM_199282.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100976505; called by muse, mutect2, varscan2
- ARHGAP29 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs757995655, COSV53109880; called by muse, mutect2, varscan2
- ARHGAP30 | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV100920244; called by muse, varscan2
- ARHGAP30 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV100920245; called by muse, varscan2
- ARHGAP30 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs371385714; called by muse, mutect2, varscan2
- ARHGAP31 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs757724432, COSV99957043; called by muse, mutect2, varscan2
- ARHGAP31 | c.3066G>T p.Q1022H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as COSV99957046; called by muse, mutect2, varscan2
- ARHGAP35 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.745); catalogued as COSV68330416; called by mutect2, varscan2
- ARHGAP35 | c.3152T>A p.I1051N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV68330036; called by muse, mutect2, varscan2
- ARHGAP5 | c.1639G>T p.G547* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100565333, COSV61539724; called by muse, mutect2, varscan2
- ARHGAP6 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs764970856, COSV100272774; called by muse, mutect2, varscan2
- ARHGAP9 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100712429; called by muse, mutect2
- ARHGEF10L | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs769813234, COSV100769788; called by muse, varscan2
- ARHGEF15 | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100730038; called by muse, mutect2, varscan2
- ARHGEF15 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); catalogued as rs145017019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF17 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV99735506; called by muse, mutect2, varscan2
- ARHGEF17 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV99735512; called by muse, varscan2
- ARHGEF17 | c.5710C>T p.H1904Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99735521; called by muse, mutect2, varscan2
- ARHGEF4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100388020, COSV58132529; called by muse, mutect2, varscan2
- ARHGEF40 | c.1387G>T p.G463W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); catalogued as COSV100070297; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 55/124 reads (44%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARID1A | c.4559G>A p.G1520D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100251516, COSV61389733; called by muse, mutect2, varscan2
- ARID4A | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100794216; called by muse, mutect2, varscan2
- ARID4B | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99935553; called by muse, mutect2
- ARID4B | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | catalogued as COSV51613820; called by muse, mutect2
- ARID5A | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100673587; called by muse, mutect2, varscan2
- ARL10 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100119041; called by muse, mutect2
- ARL14EP | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV99955929; called by muse, mutect2
- ARMC10 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100085731; called by mutect2, varscan2
- ARMC3 | c.1827C>T p.Y609= | Splice Region (SNP) | VAF 25/63 reads (40%) | catalogued as rs371745700, COSV53057401; called by muse, mutect2, varscan2
- ARMC3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473023972, COSV53059669; called by muse, mutect2, varscan2
- ARMC4 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs760325470, COSV100536722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMC5 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs552657393, COSV99192501; called by muse, mutect2, varscan2
- ARMCX3 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 35/42 reads (83%) | catalogued as COSV100362250; called by muse, mutect2, varscan2
- ARMH3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs1328792113, COSV60752497; called by muse, mutect2, varscan2
- ARMT1 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100939787; called by muse, mutect2, varscan2
- ARNT | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.24); catalogued as COSV100591132; called by muse, mutect2, varscan2
- ARNT2 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100308956; called by muse, mutect2, varscan2
- ARNTL | c.907G>T p.E303* (on ENST00000403290 / NM_001297719.2; = p.E302* on NM_001178.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100724712, COSV62986216; called by muse, mutect2, varscan2
- ARNTL2 | c.932T>G p.F311C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99667730; called by muse, mutect2, varscan2
- ARSH | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs774297748, COSV101139827, COSV66963896; called by muse, mutect2, varscan2
- ARSI | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs374583135; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs753865255; called by mutect2, varscan2
- ART3 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs1369263807, COSV100587751; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100727209; called by muse, mutect2, varscan2
- ASB15 | c.1105C>A p.L369I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51925505, COSV99306493; called by muse, mutect2, varscan2
- ASB5 | c.927A>T p.R309S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99641625; called by muse, mutect2, varscan2
- ASB9 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV100995481; called by muse, mutect2
- ASCC2 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs1199994247, COSV100316248, COSV57071819; called by muse, mutect2, varscan2
- ASCC2 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100316249; called by muse, mutect2, varscan2
- ASCL3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100366879; called by muse, varscan2
- ASH1L | c.8053C>T p.R2685C (on ENST00000368346 / NM_001366177.2; = p.R2680C on NM_018489.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100853396; called by muse, mutect2, varscan2
- ASMT | c.666C>A p.F222L (on ENST00000381229; = p.F250L on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV101172451; called by muse, mutect2
- ASPM | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV99660241; called by muse, mutect2, varscan2
- ASTL | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs767172858, COSV60904431; called by muse, mutect2, varscan2
- ASTL | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs145986421; called by mutect2, varscan2
- ASTN1 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373152514, COSV62494292; called by muse, mutect2, varscan2
- ASTN1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as COSV99921458; called by muse, mutect2, varscan2
- ASTN2 | c.1714C>A p.L572M (on ENST00000313400 / NM_001365069.1; = p.L521M on NM_014010.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57771522; called by muse, mutect2, varscan2
- ASXL2 | c.3895G>T p.D1299Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99711005; called by muse, mutect2, varscan2
- ATAD2 | c.4094G>A p.R1365Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs111422836, COSV54881834; called by muse, mutect2, varscan2
- ATAD2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99784619; called by muse, mutect2, varscan2
- ATAD2 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as COSV99784621; called by muse, mutect2, varscan2
- ATE1 | c.841A>G p.S281G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs745816449, COSV99817054; called by mutect2, varscan2
- ATF2 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as rs1291506008, COSV99908670; called by muse, mutect2, varscan2
- ATF7IP2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1409037854, COSV100202603; called by muse, mutect2, varscan2
- ATF7IP2 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100202604; called by muse, mutect2, varscan2
- ATG2A | c.2493G>T p.E831D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101034295; called by muse, mutect2, varscan2
- ATG7 | c.215+2T>C p.X72_splice | Splice Site (SNP) | VAF 26/65 reads (40%) | catalogued as COSV61616732; called by muse, mutect2, varscan2
- ATG7 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs557310519, COSV100607235; called by muse, mutect2, varscan2
- ATG9A | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772576; called by muse, mutect2, varscan2
- ATG9B | c.2164G>T p.G722W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99871581; called by muse, mutect2
- ATL2 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100184608; called by muse, mutect2, varscan2
- ATM | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs587780619, CM0910496, COSV53733830; ClinVar: uncertain significance; called by muse, varscan2
- ATM | c.3568G>C p.V1190L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs876660708, COSV99589444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.6270C>A p.D2090E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1565503097, COSV99589446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs202137938, COSV100791177; called by muse, mutect2, varscan2
- ATP10A | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791178; called by muse, varscan2
- ATP10A | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs144743073; called by muse, mutect2, varscan2
- ATP10A | c.848-1G>A p.X283_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100791180, COSV63515329; called by muse, mutect2, varscan2
- ATP10D | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99905561; called by muse, mutect2, varscan2
- ATP11C | c.2026C>A p.L676I | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557819; called by muse, mutect2, varscan2
- ATP13A2 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100454127; called by muse, mutect2, varscan2
- ATP1A1 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99814397; called by muse, mutect2, varscan2
- ATP1A1 | c.2712G>T p.Q904H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99814402; called by muse, mutect2, varscan2
- ATP1A4 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368032000; called by muse, mutect2, varscan2
- ATP1B4 | c.977C>A p.P326H (on ENST00000218008 / NM_001142447.3; = p.P322H on NM_012069.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV99486306; called by muse, mutect2
- ATP2A1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1333098448, COSV100837287; called by muse, mutect2, varscan2
- ATP2A3 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV99989107; called by muse, mutect2, varscan2
- ATP2A3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs144288676; called by muse, mutect2, varscan2
- ATP2B1 | c.2275T>C p.W759R | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99665626; called by muse, mutect2
- ATP2B3 | c.275dup p.Q94Afs*42 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | catalogued as rs1557006211; called by mutect2, pindel, varscan2
- ATP2B4 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs200430665, COSV100397153; called by muse, mutect2, varscan2
- ATP2C1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as rs778339531, COSV60762837; called by muse, mutect2, varscan2
- ATP2C1 | c.1413+1G>A p.X471_splice | Splice Site (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100146653; called by muse, mutect2
- ATP2C1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358466833, COSV60756111; called by muse, mutect2, varscan2
- ATP2C2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99297991; called by muse, mutect2, varscan2
- ATP4A | c.3019G>A p.G1007S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.488); catalogued as rs146641851; called by muse, mutect2, varscan2
- ATP4A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52868670; called by muse, mutect2, varscan2
- ATP5F1B | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56261053; called by muse, mutect2, varscan2
- ATP5F1C | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs1277576483, COSV100184320; called by muse, mutect2, varscan2
- ATP5MC2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100101000; called by muse, mutect2, varscan2
- ATP6V0A2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs777798260, COSV100376989; called by muse, varscan2
- ATP6V0A2 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100376990; called by muse, varscan2
- ATP6V0D2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs759946535, COSV53415469; called by muse, mutect2, varscan2
- ATP6V0E1 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274653184, COSV99439112; called by muse, mutect2, varscan2
- ATP6V1C1 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1301487065, COSV101214967, COSV101215139; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1235A>C p.D412A (on ENST00000272238 / NM_001039362.2; = p.D366A on NM_144583.4) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99694625; called by muse, mutect2, varscan2
- ATP6V1H | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778638; called by muse, mutect2, varscan2
- ATP7A | c.3631C>T p.R1211W | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs782786661, COSV100430723; called by muse, mutect2, varscan2
- ATP7A | c.3734C>A p.S1245Y | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100430727; called by muse, mutect2, varscan2
- ATP7B | c.4163C>T p.A1388V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs371458882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99666391; called by muse, mutect2, varscan2
- ATP8B1 | c.1820-1G>C p.X607_splice | Splice Site (SNP) | VAF 35/96 reads (36%) | catalogued as rs199474675, CS128782, COSV99377231; called by muse, mutect2, varscan2
- ATP9B | c.3095T>C p.L1032P | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100303479; called by muse, mutect2, varscan2
- ATPAF1 | c.529G>A p.A177T (on ENST00000574428; = p.A200T on NM_022745.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs367951336; called by muse, mutect2, varscan2
- ATRN | c.2441T>C p.L814S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV99497075; called by muse, mutect2, varscan2
- ATRNL1 | c.4031C>T p.A1344V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100370463; called by muse, mutect2, varscan2
- ATXN3 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 16/224 reads (7%) | catalogued as COSV100515308; called by muse, mutect2
- ATXN7 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368917711; called by muse, mutect2, varscan2
- ATXN7 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99894327; called by muse, mutect2, varscan2
- AUP1 | c.672-1G>T p.X224_splice | Splice Site (SNP) | VAF 35/82 reads (43%) | catalogued as COSV99239655; called by muse, mutect2, varscan2
- AURKB | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100298714; called by muse, mutect2, varscan2
- AVEN | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100145475; called by muse, mutect2, varscan2
- AVIL | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.855); catalogued as COSV57683619, COSV99142342; called by muse, mutect2, varscan2
- AVPI1 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV101033296; called by muse, mutect2, varscan2
- AVPR1A | c.609C>A p.C203* | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | catalogued as COSV100146847; called by muse, mutect2, varscan2
- AWAT2 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as rs1197229114, COSV52144617, COSV99339639; called by muse, mutect2
- AXIN1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140421619; called by muse, mutect2, varscan2
- AXL | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as rs200936572, COSV99996494; called by muse, mutect2, varscan2
- AZGP1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377632165; called by muse, mutect2, varscan2
- AZIN1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV100457537; called by muse, mutect2, varscan2
- AZU1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771363257, COSV99297266; called by muse, mutect2, varscan2
- B3GALNT2 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs751445150, COSV100782808; called by muse, mutect2, varscan2
- B3GALT4 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as rs947664721, COSV101005621; called by muse, mutect2
- B3GAT1 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1268973365, COSV100437878; called by muse, mutect2, varscan2
- B3GLCT | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs766659397, COSV100587275; called by mutect2, varscan2
- B3GNT2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57344225; called by muse, mutect2, varscan2
- B3GNT2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100114155, COSV57343935; called by muse, mutect2, varscan2
- B3GNT7 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs765053112, COSV55007155; called by mutect2, varscan2
- B4GALNT4 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1312225122, COSV100327475; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BABAM2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558639513, COSV59622455, COSV59628195; called by muse, mutect2, varscan2
- BACH1 | c.932A>G p.H311R | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV99728176; called by muse, mutect2, varscan2
- BAG6 | c.3163G>T p.V1055F (on ENST00000676571; = p.V1008F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1363409285, COSV99276954; called by muse, mutect2, varscan2
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | catalogued as rs1555653824; called by pindel, varscan2
- BAIAP2L2 | c.1430G>A p.S477N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as rs1382271667, COSV100260085; called by muse, varscan2
- BAIAP2L2 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs748452614, COSV100260088; called by muse, varscan2
- BANF2 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55724108; called by muse, mutect2, varscan2
- BANK1 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs761282774, COSV59848357; called by muse, mutect2, varscan2
- BAP1 | c.1636T>C p.Y546H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV99963905; called by muse, mutect2, varscan2
- BARHL1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765562421, COSV99707565; called by muse, varscan2
- BAZ1A | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as COSV62410045; called by muse, mutect2, varscan2
- BAZ1A | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100701138, COSV62412036; called by muse, mutect2, varscan2
- BAZ1B | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs565295237, COSV100289724; called by muse, mutect2, varscan2
- BAZ1B | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV59990830; called by muse, mutect2, varscan2
- BAZ1B | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.388); catalogued as COSV100289725; called by muse, mutect2, varscan2
- BAZ2A | c.5362C>T p.R1788W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1319339868, COSV99465951; called by muse, mutect2, varscan2
- BAZ2B | c.3050C>A p.A1017D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99680956; called by muse, mutect2, varscan2
- BBS10 | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as CD102573, COSV99674960; called by muse, mutect2, varscan2
- BBS7 | c.2098C>A p.L700M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99144901; called by muse, mutect2, varscan2
- BCAR3 | c.2471A>G p.E824G | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99550696; called by muse, mutect2, varscan2
- BCAS3 | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV101175827; called by muse, mutect2, varscan2
- BCAS4 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as rs564853296, COSV52813195; called by muse, mutect2, varscan2
- BCCIP | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99501623; called by muse, mutect2, varscan2
- BCL2L1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs372986095; called by mutect2, varscan2
- BCL6 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.197); catalogued as COSV99215616; called by muse, mutect2, varscan2
- BCL6 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as rs768771889, COSV99215620; called by muse, mutect2, varscan2
- BCL9 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.735); catalogued as COSV99325062; called by muse, mutect2, varscan2
- BCL9 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs782671101, COSV52345913, COSV99325067; called by muse, mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs756382429; called by mutect2, pindel, varscan2
- BCLAF1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs768427687, COSV100786640; called by muse, mutect2, varscan2
- BCOR | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201651782, COSV60698468; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 22/36 reads (61%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCR | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.279); catalogued as rs201711782; called by muse, mutect2, varscan2
- BDH1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs746963745, COSV64020433; called by muse, mutect2, varscan2
- BDKRB1 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs755140763, COSV99387831; called by muse, mutect2, varscan2
- BDP1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); catalogued as COSV100703017; called by muse, mutect2, varscan2
- BDP1 | c.1535G>A p.C512Y | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100703018; called by muse, mutect2, varscan2
- BDP1 | c.4543C>A p.P1515T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as COSV100703021, COSV62430966; called by muse, mutect2, varscan2
- BEND4 | c.707T>C p.M236T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); catalogued as COSV101549741; called by muse, mutect2, varscan2
- BEX5 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV61328576; called by muse, varscan2
- BFSP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200874347, COSV56588428; called by muse, mutect2, varscan2
- BHLHE41 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99658271; called by muse, mutect2, varscan2
- BICD1 | c.1666A>G p.R556G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV99862369; called by muse, mutect2, varscan2
- BICD2 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794093; called by muse, mutect2, varscan2
- BICDL1 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99985813; called by muse, mutect2, varscan2
- BICRA | c.2935dup p.A979Gfs*86 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs756990560; called by mutect2, varscan2
- BIN1 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV99387922; called by muse, mutect2, varscan2
- BIRC3 | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99679869; called by muse, mutect2, varscan2
- BIRC6 | c.5380G>A p.D1794N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101428244; called by muse, mutect2, varscan2
- BIRC6 | c.7550G>A p.S2517N | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs776298375, COSV101428245; called by muse, mutect2, varscan2
- BIRC6 | c.10997G>A p.R3666H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.921); catalogued as rs759663407, COSV101428247; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV57280657, COSV99958723; called by muse, mutect2, varscan2
- BLID | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV101601719; called by muse, mutect2, varscan2
- BLMH | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55585130; called by muse, mutect2, varscan2
- BLNK | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99813848; called by muse, mutect2, varscan2
- BMI1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100936387; called by muse, mutect2, varscan2
- BMP3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99261626; called by muse, mutect2
- BMP3 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99261628; called by muse, mutect2, varscan2
- BMP4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs1166450278, COSV99816902; called by muse, mutect2, varscan2
- BMPR1B | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215797; called by muse, mutect2
- BMPR2 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as COSV101001460; called by muse, mutect2, varscan2
- BMPR2 | c.1958C>A p.P653H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101001464; called by muse, mutect2, varscan2
- BMT2 | c.522C>A p.C174* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99774586; called by muse, varscan2
- BNC1 | c.1667A>C p.E556A | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100597158; called by muse, mutect2, varscan2
- BNC1 | c.448A>C p.K150Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100597159, COSV61756800; called by muse, mutect2, varscan2
- BNC2 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV101033104; called by muse, mutect2, varscan2
- BNIP1 | c.371+1G>A p.X124_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99199389; called by muse, mutect2, varscan2
- BNIPL | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1026320193, COSV99764634; called by muse, mutect2, varscan2
- BOD1L1 | c.6967G>T p.D2323Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1202735790, COSV99238939, COSV99239255; called by muse, mutect2, varscan2
- BOD1L1 | c.5102C>T p.S1701F | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99238890, COSV99239260; called by muse, mutect2, varscan2
- BPIFB6 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100848513; called by muse, mutect2, varscan2
- BPNT2 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99389005; called by muse, mutect2, varscan2
- BPTF | c.7119G>A p.M2373I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs781794996, COSV100074847; called by muse, mutect2, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs777474487; called by mutect2, varscan2
- BRAP | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs768505983, COSV100554121; called by muse, mutect2, varscan2
- BRCA2 | c.4031del p.N1344Mfs*30 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs1405264241; called by mutect2, pindel, varscan2
- BRD1 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753570026, COSV53460399; called by muse, mutect2, varscan2
- BRD1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs776625246, COSV99349695; called by mutect2, varscan2
- BRD2 | c.1178C>A p.P393H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100875663; called by muse, mutect2, varscan2
- BRD8 | c.899C>T p.P300L (on ENST00000254900 / NM_139199.2; = p.P373L on NM_006696.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV50147141, COSV99136928; called by muse, mutect2
- BRDT | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV100746346; called by muse, mutect2, varscan2
- BRF1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs763864881, COSV100527267; called by muse, varscan2
- BRF2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144896527; called by muse, mutect2, varscan2
- BRINP1 | c.1364A>C p.K455T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as COSV99775309; called by muse, mutect2, varscan2
- BRIP1 | c.3182A>G p.N1061S | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV99370002; called by muse, mutect2, varscan2
- BRIP1 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.956); catalogued as rs145601931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100121228; called by muse, mutect2, varscan2
- BRSK1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378692450, COSV100474017; called by muse, varscan2
- BRSK1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1262439727, COSV100473494; called by muse, mutect2, varscan2
- BSN | c.10266C>A p.Y3422* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | catalogued as COSV99608312; called by muse, mutect2, varscan2
- BSN | c.11653G>A p.A3885T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as rs202222119, COSV56520503; called by muse, mutect2, varscan2
- BSPRY | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as rs778338138, COSV53057958; called by muse, mutect2, varscan2
- BTAF1 | c.701G>T p.S234I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV99795291; called by muse, mutect2, varscan2
- BTBD10 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99533569; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs777776928; called by mutect2, varscan2
- BTBD3 | c.327-1G>T p.X109_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99655827; called by muse, mutect2
- BTBD7 | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs368457475; called by muse, mutect2, varscan2
- BTBD9 | c.1648C>A p.H550N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1265943159, COSV100021720; called by muse, mutect2
- BTD | c.634T>G p.F212V | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100329557; called by muse, mutect2, varscan2
- BTLA | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100569698; called by muse, mutect2, varscan2
- BTN1A1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs766105717, COSV99764351; called by muse, mutect2, varscan2
- BTN3A2 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100709634; called by muse, mutect2, varscan2
- BUB1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs975621280, COSV57063381; called by muse, mutect2, varscan2
- C10orf99 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100929355; called by muse, mutect2, varscan2
- C11orf54 | c.810del p.F270Lfs*18 (on ENST00000331239; = p.F220Lfs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | catalogued as rs1243082072; called by mutect2, pindel, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs771322722; called by mutect2, varscan2
- C12orf66 | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100320704; called by muse, mutect2, varscan2
- C12orf66 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as COSV100320707; called by muse, mutect2, varscan2
- C16orf82 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.134); catalogued as rs1567235079; called by muse, varscan2
- C16orf82 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs757633274; called by muse, varscan2
- C18orf25 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754564079, COSV56368145, COSV56368630; called by muse, mutect2, varscan2
- C19orf57 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV100694694; called by muse, mutect2, varscan2
- C1QTNF9 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs149288885; called by muse, mutect2, varscan2
- C1S | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs782412161, COSV61071351; called by muse, mutect2, varscan2
- C1orf109 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100787468; called by muse, mutect2, varscan2
- C1orf112 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs762180187, COSV99609726; called by muse, mutect2, varscan2
- C1orf146 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as rs928748020, COSV64860159; called by muse, mutect2, varscan2
- C1orf74 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV99161192; called by muse, mutect2, varscan2
- C1orf74 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99161194; called by muse, mutect2
- C1orf87 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as COSV100967045; called by muse, mutect2, varscan2
- C2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147553278; called by muse, mutect2, varscan2
- C20orf204 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1426630195, COSV53874023; called by muse, mutect2, varscan2
- C20orf27 | c.514G>A p.G172S (on ENST00000379772 / NM_001258429.2; = p.G197S on NM_001039140.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146279706; called by muse, varscan2
- C20orf96 | c.215T>C p.V72A (on ENST00000360321 / NM_153269.3; = p.V71A on NM_080571.1) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.085); catalogued as COSV100826710; called by muse, mutect2, varscan2
- C2CD2 | c.2028G>T p.K676N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV100298133; called by muse, mutect2
- C2orf80 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100378389, COSV58015956; called by muse, mutect2
- C3AR1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as rs376269642, COSV50821158; called by muse, mutect2, varscan2
- C3orf14 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs746708616, COSV99223751; called by muse, mutect2, varscan2
- C3orf38 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs199859699, COSV100007277; called by muse, mutect2, varscan2
- C4A | c.3344G>A p.G1115D | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV101418334; called by muse, mutect2, varscan2
- C4BPA | c.1086G>A p.A362= | Splice Region (SNP) | VAF 18/113 reads (16%) | catalogued as rs774171981, COSV65537808; called by muse, mutect2, varscan2
- C4orf45 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.046); catalogued as rs1367724546, COSV101465094; called by muse, mutect2, varscan2
- C4orf51 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1477279746, COSV101439992; called by muse, mutect2
- C5AR1 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61893573; called by muse, mutect2, varscan2
- C5orf24 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs937149388, COSV100574492; called by muse, mutect2, varscan2
- C7orf25 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.454); catalogued as COSV100623634; called by muse, mutect2, varscan2
- C7orf26 | c.1147A>G p.N383D | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs755644585, COSV100732893; called by muse, mutect2, varscan2
- C7orf31 | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as rs1450564061, COSV99383926; called by muse, varscan2
- C7orf31 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99383928; called by muse, mutect2, varscan2
- C9 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.8); catalogued as COSV99662019; called by muse, mutect2, varscan2
- C9orf131 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV100398087; called by muse, mutect2, varscan2
- C9orf43 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs771894456, COSV99928326; called by muse, mutect2, varscan2
- CAAP1 | c.531dup p.L178Tfs*11 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | catalogued as rs1312369665; called by mutect2, pindel, varscan2
- CABP5 | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53153692, COSV99506511; called by muse, mutect2
- CACNA1B | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99497123; called by muse, mutect2, varscan2
- CACNA1B | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99497126; called by muse, mutect2, varscan2
- CACNA1D | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99857959; called by muse, mutect2, varscan2
- CACNA1D | c.2277A>T p.E759D (on ENST00000350061 / NM_001128840.3; = p.E779D on NM_000720.4) | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.182); catalogued as COSV99857963; called by muse, mutect2, varscan2
- CACNA1D | c.6088G>A p.D2030N (on ENST00000350061 / NM_001128840.3; = p.D2050N on NM_000720.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as rs770332315, COSV99857967; called by muse, mutect2, varscan2
- CACNA1H | c.3962G>A p.G1321D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.15); catalogued as rs1043239667, COSV100672336, COSV61986588; called by muse, mutect2, varscan2
- CACNA2D1 | c.1886A>G p.Y629C (on ENST00000356253 / NM_001366867.1; = p.Y610C on NM_000722.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1246134905, COSV100666577; called by muse, mutect2, varscan2
- CACNA2D4 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759276999, COSV54952249, COSV54956396; called by muse, varscan2
- CACNB2 | c.811C>T p.H271Y (on ENST00000324631 / NM_201596.3; = p.H216Y on NM_000724.4) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as COSV99994328; called by muse, mutect2, varscan2
- CACNB3 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.206); catalogued as COSV99974863; called by muse, mutect2, varscan2
- CACNG5 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs147089270; called by muse, mutect2, varscan2
- CACNG8 | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99554977; called by muse, mutect2, varscan2
- CADM2 | c.536G>A p.R179H (on ENST00000407528 / NM_001167674.2; = p.R181H on NM_153184.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1416693838, COSV67356966, COSV67406817; called by muse, mutect2, varscan2
- CALCA | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.191); catalogued as rs782200615, COSV100524004; called by muse, mutect2, varscan2
- CALCOCO1 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100017299, COSV50428412; called by muse, mutect2, varscan2
- CALCR | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs972789445, COSV64008823; called by muse, mutect2, varscan2
- CALHM1 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs754358611, COSV100324222; called by muse, varscan2
- CALML4 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100682836; called by muse, mutect2, varscan2
- CALML5 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs199855788, COSV100981195; called by muse, mutect2, varscan2
- CALN1 | c.137G>A p.R46Q (on ENST00000329008 / NM_001017440.3; = p.R88Q on NM_031468.4) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs756920218, COSV100207231, COSV61131312; called by muse, mutect2, varscan2
- CAMK2B | c.1379G>A p.G460D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.095); catalogued as COSV99323009; called by muse, mutect2, varscan2
- CAMK2G | c.1568G>A p.R523Q (on ENST00000423381 / NM_001367518.1; = p.R460Q on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.991); catalogued as rs368660026; called by muse, varscan2
- CAMTA1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV100349036; called by muse, mutect2, varscan2
- CAMTA1 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs755139563, COSV100349041; called by muse, mutect2, varscan2
- CANT1 | c.44T>C p.M15T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1226007813, COSV100185112; called by muse, mutect2, varscan2
- CAPN1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99658613; called by muse, mutect2
- CAPN12 | c.1879-1G>T p.X627_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as rs777394551, COSV99400141; called by muse, varscan2
- CAPN13 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99699947, COSV99700186; called by muse, mutect2, varscan2
- CAPN2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541384226, COSV99688856; called by muse, mutect2, varscan2
- CAPN5 | c.883G>A p.A295T (on ENST00000456580; = p.A255T on NM_004055.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.153); catalogued as rs782335833, COSV99582061; called by muse, mutect2, varscan2
- CAPN9 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.243); catalogued as COSV99680335; called by muse, mutect2, varscan2
- CAPRIN1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100403816, COSV100404225; called by muse, varscan2
- CAPRIN2 | c.2986G>A p.V996I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746668837, COSV99195485; called by mutect2, varscan2
- CAPRIN2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749750269, COSV99195486; called by muse, mutect2, varscan2
- CAPZA2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs1464785209, COSV100753904, COSV63266205; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs762770988, COSV62756627; called by mutect2, varscan2
- CARD11 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237589286, COSV62716241; called by muse, mutect2, varscan2
- CARF | c.872G>T p.R291I | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100247639; called by muse, mutect2, varscan2
7,338 further variants in this file (5,149 protein-altering or splice-affecting, 1,992 silent, 197 other) are not listed here.
